Somatic mutation profile of tumor specimen TCGA-06-2569-01A (aliquot TCGA-06-2569-01A-01D-1494-08) from TCGA case TCGA-06-2569, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 24.4 years (8,922 days).
Specimen TCGA-06-2569-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b124cc5-eee4-4364-bb85-ac30d9ad9272.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2569-10A (Blood Derived Normal), aliquot TCGA-06-2569-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03dfb83a-f803-4380-8681-b3ebc2ffee29

The open-access MAF lists 32 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 24, Silent 4, In Frame Del 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.463_474del p.T155_R158del | In Frame Del (DEL) | VAF 51/68 reads (75%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACACA | c.7148C>T p.T2383M | Missense Mutation (SNP) | VAF 61/71 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as rs762756380; called by muse, mutect2, varscan2
- ATP10D | c.1344G>T p.M448I | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56706537; called by muse, mutect2, varscan2
- ATP5ME | c.201A>G p.I67M | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1196851072, COSV55325571; called by muse, mutect2, varscan2
- DICER1 | c.5113G>C p.E1705Q | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58615252, COSV58618257; called by muse, mutect2, varscan2
- ELN | c.1598A>G p.K533R | Missense Mutation (SNP) | VAF 112/125 reads (90%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.124); catalogued as rs1554683304, COSV52709500; called by muse, mutect2, varscan2
- EVI2B | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV58363805; called by muse, mutect2, varscan2
- FADS6 | c.884C>G p.A295G | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.897); catalogued as COSV100043902, COSV59602113; called by muse, mutect2, varscan2
- GLIS1 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV56547266; called by muse, mutect2, varscan2
- IGSF8 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58757811; called by muse, mutect2, varscan2
- IRAK4 | c.431G>T p.S144I | Missense Mutation (SNP) | VAF 73/283 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101471829; called by muse, mutect2, varscan2
- ITGAD | c.1254C>A p.N418K | Missense Mutation (SNP) | VAF 69/81 reads (85%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs759237625, COSV66757588; called by muse, mutect2, varscan2
- KBTBD2 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.441); catalogued as rs763551950, COSV58363276; called by muse, mutect2, varscan2
- KLK15 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56826605; called by muse, mutect2, varscan2
- LHPP | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs202090877, COSV64328929; called by muse, mutect2, varscan2
- MANBAL | c.193A>G p.K65E | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.209); catalogued as COSV65311553; called by muse, mutect2, varscan2
- MAP6 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 108/256 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs201737872, COSV59075217; called by muse, mutect2, varscan2
- OBSCN | c.15484G>A p.D5162N | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52763749; called by muse, mutect2
- PCDH19 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV55261180; called by muse, mutect2, varscan2
- RAG1 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as CM102781, COSV55024772; called by muse, mutect2, varscan2
- SPDL1 | c.1798A>G p.T600A | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV54667781; called by muse, varscan2
- TRIM46 | c.1040G>A p.S347N | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV55278618; called by muse, mutect2, varscan2
- WDFY2 | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV53288628; called by muse, mutect2, varscan2
- WNK2 | c.3850G>T p.G1284C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV52938628; called by muse, mutect2, varscan2
- AMY2A | c.1153G>T p.V385F | Missense Mutation (SNP) | VAF 110/703 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); called by mutect2, varscan2
- DICER1 | c.3158_3175del p.C1053_L1058del | In Frame Del (DEL) | VAF 74/354 reads (21%) | called by mutect2, pindel, varscan2
- HOXD8 | c.833_834del p.Q278Rfs*62 | Frame Shift Del (DEL) | VAF 20/75 reads (27%) | called by mutect2, pindel, varscan2
- NF1 | c.5042dup p.N1681Kfs*3 (on ENST00000358273 / NM_001042492.3; = p.N1660Kfs*3 on NM_000267.3) | Frame Shift Ins (INS) | VAF 138/208 reads (66%) | called by mutect2, pindel, varscan2
- ANAPC2 | c.1788G>T p.L596= | Silent (SNP) | VAF 45/151 reads (30%) | catalogued as COSV60569553; called by muse, mutect2, varscan2
- CD93 | c.1107C>T p.C369= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as rs1288369883, COSV55664545; called by muse, mutect2
- COL19A1 | c.3270G>A p.L1090= | Silent (SNP) | VAF 9/178 reads (5%) | catalogued as COSV59570531; called by muse, mutect2
- GAS2L2 | c.1395C>T p.A465= | Silent (SNP) | VAF 67/170 reads (39%) | catalogued as rs782336958; called by muse, mutect2, varscan2
